TCGA case TCGA-VG-A8LO — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Institute of Human Virology Nigeria. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8628f1b2-3763-4ba9-a375-083874bb18f2

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: Nigeria; Age at index: 55 years; Vital status: Dead; Days to death: 24 days.

Diagnoses (1)
1. Papillary serous cystadenocarcinoma: ICD-O-3 morphology code: 8460/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 55.5 years (20,274 days); Year of diagnosis: 2013; Method of diagnosis: Excisional Biopsy; FIGO stage: Stage IV; Tumor grade: GB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Consistent pathology review: Yes; Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 8 days; Days to treatment end: 8 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 24 days; Disease response: With Tumor.
- Karnofsky performance status: 50; ECOG performance status: 4; Timepoint: Other.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VG-A8LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Days to sample procurement: 0 days; Initial weight: 260 mg.
  Slide TCGA-VG-A8LO-01A-01-DX1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VG-A8LO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 24 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 24 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 24 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VG-A8LO-01A-11D-A402-01): tumor purity 0.93, ploidy 2.03, whole-genome doublings 0.
